Gene-level copy-number profile of tumor specimen C3N-06053-02 from CPTAC case C3N-06053, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIID; Age at diagnosis: 89.1 years (32,550 days).
Specimen C3N-06053-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8813e0f6-0f86-48f1-ae37-a596349f39f4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-06053-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/a35fb358-070f-4ff1-b2a3-4580a6960418

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 521; copy number 1: 396; copy number 2: 11,801; copy number 3: 8,332; copy number 4: 36,695; copy number 5: 208; copy number 6: 280; copy number 7: 75; copy number 8: 34; copy number 9: 305; copy number 10: 46; copy number 11: 103; copy number 12: 96; copy number 13: 14; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:65,189,995–65,193,610, 1 gene: BMS1P12.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–2): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.
- chr17:22,233,926–22,266,392, 1 gene: LINC02002.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 565 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:4,604,944–4,774,184, 7 genes, copy number 9 (within-gene range 1–9): AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1.
- chr12:10,030,678–10,066,031, 1 gene, copy number 9 (within-gene range 6–9): CLEC9A.
- chr12:10,069,554–12,471,233, 83 genes, copy number 9–11 (within-gene range 1–11) (broad region; genes not listed).
- chr12:19,724,435–23,251,499, 52 genes, copy number 9–13: RNU1-146P, AC024901.1, TCP1P3, LINC02398, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:27,935,523–30,879,268, 38 genes, copy number 9–11 (within-gene range 8–11): AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, CAPRIN2, AC010198.1, LINC00941, AC010198.2.
- chr12:31,111,652–32,383,633, 46 genes, copy number 10 (within-gene range 1–10): AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1.
- chr22:17,787,649–18,024,561, 1 gene, copy number 9 (within-gene range 7–12): MICAL3.
- chr22:17,980,868–18,205,915, 14 genes, copy number 9–12: MIR648, AC016027.3, AC016027.2, RHEBP3, LINC01634, AC016027.1, PEX26, AC016027.5, AC016027.4, ARL2BPP10, TUBA8, AC008079.1, USP18, FAM230D.
- chr22:18,715,815–18,719,341, 1 gene, copy number 15: PPP1R26P4.
- chr22:18,936,411–21,982,813, 176 genes, copy number 9–12 (within-gene range 3–12) (broad region; genes not listed).
- chr22:37,608,725–39,973,721, 110 genes, copy number 9 (broad region; genes not listed).
- chr22:42,438,023–43,812,337, 36 genes, copy number 9–12 (within-gene range 2–12): AL022316.1, SERHL, RRP7A, SERHL2, RRP7BP, RN7SKP80, RNU6-513P, POLDIP3, RNU12, Z93241.1, CYB5R3, ATP5MGL, A4GALT, Y_RNA, RPL5P34, GOLGA2P4, AL049757.1, ARFGAP3, PACSIN2, AL049758.1, TTLL1-AS1, TTLL1, AL022237.1, BIK, MCAT, TSPO, TTLL12, SCUBE1, SCUBE1-AS2, Z82214.1, SCUBE1-AS1, LINC01639, MPPED1, BX546033.1, EFCAB6-AS1, EFCAB6.

Autosomal genes at a single copy (total copy number 1): 396. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
